Somatic mutation profile of tumor specimen TCGA-06-0648-01A (aliquot TCGA-06-0648-01A-01W-0323-08) from TCGA case TCGA-06-0648, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.0 years (28,477 days).
Specimen TCGA-06-0648-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebe00ed2-55ab-4ff4-ad0b-1b2cbf0c5252.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0648-10A (Blood Derived Normal), aliquot TCGA-06-0648-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/379d8213-27fa-47d5-a361-c88ea3249220

The open-access MAF lists 59 somatic variants for this specimen: 46 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 35, Silent 13, Frame Shift Ins 6, Nonsense Mutation 2, Frame Shift Del 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LDLRAP1 | c.603dup p.S202Lfs*19 | Frame Shift Ins (INS) | VAF 8/74 reads (11%) | catalogued as rs781585299; ClinVar: pathogenic; called by pindel, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 44/342 reads (13%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- ABCF3 | c.1120C>A p.P374T | Missense Mutation (SNP) | VAF 209/362 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV53052758; called by muse, mutect2, varscan2
- ADGRD1 | c.1113G>T p.Q371H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55440410; called by muse, mutect2, varscan2
- AGPAT4 | c.907dup p.R303Pfs*60 | Frame Shift Ins (INS) | VAF 13/80 reads (16%) | catalogued as rs750826126; called by mutect2, varscan2
- ANO5 | c.160T>G p.F54V | Missense Mutation (SNP) | VAF 139/333 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV61085320; called by muse, mutect2, varscan2
- ANP32E | c.299T>C p.I100T | Missense Mutation (SNP) | VAF 109/251 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58482315; called by muse, mutect2, varscan2
- ATP6V1G1 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 138/328 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1393915080, COSV65014128; called by muse, mutect2, varscan2
- BCAM | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs750550926, COSV54301352; called by muse, mutect2, varscan2
- CABIN1 | c.3673G>A p.V1225I | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.033); catalogued as rs528073328, COSV54082295; called by muse, mutect2, varscan2
- CANX | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 564/1294 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs753869333, COSV56004337; called by muse, mutect2, varscan2
- CCDC60 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs761390907, COSV59544403; called by muse, mutect2
- CEACAM7 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 175/390 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as rs369677539; called by muse, mutect2, varscan2
- COL27A1 | c.5236C>T p.R1746W | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763342715, COSV61926512; called by muse, mutect2, varscan2
- CXCL6 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs149811429; called by muse, mutect2
- DBT | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.007); catalogued as rs533707792, COSV64495530; ClinVar: likely benign; called by muse, mutect2, varscan2
- DMXL1 | c.5373A>G p.I1791M | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV60712418; called by muse, mutect2
- FOXR2 | c.782A>C p.D261A | Missense Mutation (SNP) | VAF 122/135 reads (90%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59258522; called by muse, mutect2, varscan2
- FPR2 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 258/604 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.379); catalogued as rs192933693, COSV60672310; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 32/153 reads (21%) | catalogued as rs749150409; called by mutect2, varscan2
- IFT46 | c.683C>T p.P228L (on ENST00000264021 / NM_001168618.2; = p.P279L on NM_020153.3) | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as rs1018041184; called by muse, mutect2
- LGALS13 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 79/359 reads (22%) | catalogued as rs534285827, COSV55680035; called by muse, mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 50/254 reads (20%) | catalogued as rs777328830; called by mutect2, varscan2
- MCM4 | c.2503A>G p.I835V | Missense Mutation (SNP) | VAF 73/181 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs747765310, COSV50623927; called by muse, mutect2, varscan2
- MYOM2 | c.3775G>A p.E1259K | Missense Mutation (SNP) | VAF 24/576 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); catalogued as rs767506341, COSV50701963; called by muse, mutect2
- NPNT | c.840C>A p.D280E | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.08); catalogued as COSV59754052; called by muse, mutect2
- OR4D2 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 226/456 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as COSV73459770; called by muse, mutect2, varscan2
- OR5D16 | c.662C>A p.A221E | Missense Mutation (SNP) | VAF 254/594 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV65722091; called by muse, mutect2, varscan2
- PAAF1 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1185994727, COSV60155681; called by muse, mutect2, varscan2
- PCDH7 | c.1223A>G p.E408G | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.672); catalogued as COSV62339367; called by muse, mutect2, varscan2
- RRAGA | c.867_868insTTG p.N289_I290insL | In Frame Ins (INS) | VAF 119/373 reads (32%) | catalogued as COSV100998180; called by mutect2, pindel, varscan2
- RRP1B | c.1186C>T p.L396F | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.216); catalogued as COSV61479163; called by muse, mutect2, varscan2
- SERPINA6 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs747671539, COSV58585130; called by muse, mutect2, varscan2
- SHOX | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV61860941; called by muse, mutect2
- SLC16A6 | c.294dup p.L99Afs*34 | Frame Shift Ins (INS) | VAF 16/120 reads (13%) | catalogued as rs782184620; called by mutect2, varscan2
- SLC29A4 | c.287A>G p.H96R | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs1307878354, COSV51874462; called by muse, mutect2, varscan2
- SLIT3 | c.3520G>A p.A1174T | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs200822063, COSV60593379; called by muse, mutect2, varscan2
- SMYD2 | c.1032C>A p.Y344* | Nonsense Mutation (SNP) | VAF 116/264 reads (44%) | catalogued as COSV65290952; called by muse, mutect2, varscan2
- TMEM241 | c.278T>A p.L93Q | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV67244076; called by muse, mutect2, varscan2
- UTRN | c.4043T>A p.V1348D | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.91); catalogued as COSV62336264; called by muse, mutect2, varscan2
- ZNF417 | c.280T>G p.C94G | Missense Mutation (SNP) | VAF 86/341 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV56309331; called by muse, mutect2, varscan2
- ABCF1 | c.1204del p.E402Nfs*11 (on ENST00000326195 / NM_001025091.2; = p.E364Nfs*11 on NM_001090.3) | Frame Shift Del (DEL) | VAF 102/290 reads (35%) | called by mutect2, pindel, varscan2
- FBXO22 | c.336del p.S113Vfs*37 | Frame Shift Del (DEL) | VAF 34/177 reads (19%) | called by mutect2, pindel, varscan2
- MLLT6 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- SERPINA1 | c.680C>A p.T227N | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.4); called by muse, mutect2
- USH2A | c.12119G>C p.R4040P | Missense Mutation (SNP) | VAF 16/596 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.106); called by muse, mutect2
- C12orf66 | c.561C>T p.F187= | Silent (SNP) | VAF 102/226 reads (45%) | catalogued as COSV61323283; called by muse, mutect2, varscan2
- DCLK1 | c.990G>A p.S330= | Silent (SNP) | VAF 25/176 reads (14%) | catalogued as rs200783749, COSV55171920; called by muse, mutect2, varscan2
- DUOX2 | c.3162C>T p.G1054= | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as rs372592162; called by muse, mutect2, varscan2
- GCSAM | c.402T>C p.P134= | Silent (SNP) | VAF 61/530 reads (12%) | catalogued as COSV58263514; called by muse, mutect2, varscan2
- LMAN2 | c.381C>T p.N127= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs372993074; called by muse, mutect2, varscan2
- LRFN2 | c.2196G>A p.A732= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs762064936, COSV57827810; called by muse, mutect2
- LRRK1 | c.2976C>T p.P992= | Silent (SNP) | VAF 57/91 reads (63%) | catalogued as COSV52612912; called by muse, mutect2, varscan2
- PGAP4 | c.693C>T p.R231= | Silent (SNP) | VAF 81/183 reads (44%) | catalogued as rs756188298, COSV66387748; called by muse, mutect2, varscan2
- RMND5A | c.702G>A p.L234= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as COSV52153852; called by muse, mutect2
- SLC39A12 | c.942G>A p.R314= | Silent (SNP) | VAF 78/96 reads (81%) | catalogued as COSV66198569, COSV66200422; called by muse, mutect2, varscan2
- SMC2 | c.2145A>G p.L715= | Silent (SNP) | VAF 42/150 reads (28%) | catalogued as COSV53958701; called by muse, mutect2, varscan2
- STK10 | c.2733G>A p.K911= | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as COSV51574401; called by muse, mutect2, varscan2
- TLL1 | c.1233C>T p.D411= | Silent (SNP) | VAF 104/258 reads (40%) | catalogued as rs764830976, COSV50261673; called by muse, mutect2, varscan2
